Gene-level copy-number profile of tumor specimen TCGA-D3-A2JC-06A from TCGA case TCGA-D3-A2JC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 53.8 years (19,644 days).
Specimen TCGA-D3-A2JC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.04ee9df4-8d84-4a40-bf52-b9931638c3e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2JC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cddf8d8d-3459-4fe5-a3ad-d2606bb2554f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 845; copy number 2: 16,813; copy number 3: 17,290; copy number 4: 19,111; copy number 5: 4,103; copy number 6: 1,022; copy number 7: 38; copy number 8: 182; copy number 9: 56; copy number 10: 48; copy number 11: 16; copy number 12: 67; copy number 13: 57; copy number 14: 4; copy number 15: 3; copy number 16: 22; copy number 17: 83; copy number 20: 15; copy number 21: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2JC-06A-11D-A192-01): tumor purity 0.47, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:81,208,568–81,992,436, 11 genes (within-gene range 0–2): AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2.
- chr6:120,526,294–120,526,400, 1 gene: RNU6-214P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 403 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:208,255,247–208,920,664, 10 genes, copy number 9: IDH1-AS1, PIKFYVE, MYL6BP1, PTH2R, ARPC1BP1, H3P9, AC019185.1, AC019185.2, AC109824.1, RNA5SP117.
- chr2:228,475,224–229,923,239, 11 genes, copy number 9 (within-gene range 5–9): LINC01807, AC012070.1, RPL7L1P10, PID1, RPL17P14, RN7SKP283, DNER, AC008273.1, RNU7-9P, AC007559.1, TRIP12.
- chr5:2,712,591–2,788,549, 5 genes, copy number 10–20: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1.
- chr5:3,357,264–3,601,403, 5 genes, copy number 11: LINC01019, LINC02162, LINC01017, IRX1, AC016595.1.
- chr5:4,436,850–5,376,836, 17 genes, copy number 11–20: AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1.
- chr5:6,134,303–7,219,291, 20 genes, copy number 10–14 (within-gene range 1–14): AC026797.1, HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1.
- chr5:8,157,541–13,944,543, 93 genes, copy number 10–21 (within-gene range 10–33) (broad region; genes not listed).
- chr5:14,661,808–24,480,057, 132 genes, copy number 11–21 (broad region; genes not listed).
- chr5:25,404,733–27,496,994, 17 genes, copy number 9 (within-gene range 3–9): AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL.
- chr5:28,213,359–28,287,807, 2 genes, copy number 11: AC093300.1, LINC02103.
- chr5:29,516,005–29,516,504, 1 gene, copy number 12: AC027345.1.
- chr5:29,881,709–29,983,114, 3 genes, copy number 15: AC010374.1, RN7SKP207, AC018765.1.
- chr5:32,124,716–32,523,865, 10 genes, copy number 12: GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1.
- chr5:32,646,564–32,888,145, 4 genes, copy number 12: LINC02061, AC008766.1, NPR3, AC025459.1.
- chr22:34,191,194–34,704,885, 4 genes, copy number 16: Z68323.1, AL021877.1, AL021877.2, Z82196.1.
- chr22:38,667,585–38,738,765, 7 genes, copy number 9 (within-gene range 6–9): AL021707.2, AL021707.9, TOMM22, JOSD1, GTPBP1, PRDX3P1, AL021707.5.
- chr22:38,734,730–38,749,041, 5 genes, copy number 9: AL021707.3, AL021707.8, AL021707.1, AL021707.6, AL021707.7.
- chr22:38,861,422–40,335,808, 45 genes, copy number 13 (within-gene range 8–13): CBX6, AL022318.5, AL022318.1, APOBEC3A, APOBEC3B, APOBEC3B-AS1, APOBEC3C, AL022318.4, APOBEC3D, APOBEC3F, AL022318.2, APOBEC3G, AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1, MGAT3, MGAT3-AS1, MIEF1, AL022312.1, ATF4, RPS19BP1, CACNA1I, ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52.
- chr22:45,604,432–45,845,307, 6 genes, copy number 9 (within-gene range 1–9): LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1.
- chr22:47,259,366–47,487,111, 3 genes, copy number 10: Z83836.1, Z82186.1, LINC01644.
- chr22:49,166,421–49,266,080, 3 genes, copy number 12: Z82202.2, RPL35P8, Z82202.1.

Autosomal genes at a single copy (total copy number 1): 845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
